Gene-level copy-number profile of tumor specimen TCGA-D9-A4Z2-01A from TCGA case TCGA-D9-A4Z2, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 50.6 years (18,469 days).
Specimen TCGA-D9-A4Z2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.7ddf8bbc-80f7-45a5-a726-e82bc2da6c26.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D9-A4Z2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/69b9b3b6-0280-4e67-a2ed-97f211019013

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 124; copy number 1: 13,293; copy number 2: 40,038; copy number 3: 4,711; copy number 4: 1,425; copy number 5: 92; copy number 6: 106; copy number 9: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D9-A4Z2-01A-11D-A24Q-01): tumor purity 0.89, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 124 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:10,532,145–12,159,148, 12 genes: AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1.
- chr9:21,394,888–31,645,160, 107 genes (broad region; genes not listed).
- chr10:87,817,928–87,971,930, 5 genes (within-gene range 0–1): CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 229 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–2,184,820, 78 genes, copy number 5–9 (broad region; genes not listed).
- chr5:4,866,521–5,320,304, 10 genes, copy number 5 (within-gene range 3–5): AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1.
- chr5:6,371,874–7,219,291, 17 genes, copy number 5 (within-gene range 3–5): MED10, AC093307.1, UBE2QL1, AC027334.1, LINC01018, NSUN2, SRD5A1, LINC02102, TENT4A, LINC02236, AC122710.2, MIR4278, LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1.
- chr5:8,012,377–8,080,761, 2 genes, copy number 6: AC116361.1, AC091941.1.
- chr5:9,498,401–12,804,363, 56 genes, copy number 6–9 (within-gene range 4–9): AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1, CTNND2, RNU6-429P, RNU6-679P, AC106771.1, LINC01194.
- chr5:15,500,180–15,939,795, 1 gene, copy number 5 (within-gene range 2–5): FBXL7.
- chr5:15,935,182–16,465,800, 9 genes, copy number 5: MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1, ZNF622.
- chr5:21,750,673–26,484,711, 50 genes, copy number 6: CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2.
- chr5:45,035,199–45,895,970, 6 genes, copy number 5–6: AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.

Autosomal genes at a single copy (total copy number 1): 10,913. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
